Somatic mutation profile of tumor specimen TCGA-05-4424-01A (aliquot TCGA-05-4424-01A-22D-1855-08) from TCGA case TCGA-05-4424, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 70.3 years (25,689 days).
Specimen TCGA-05-4424-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77852d43-b95d-4ba2-a901-f29ac0515558.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-05-4424-10A (Blood Derived Normal), aliquot TCGA-05-4424-10A-01D-1855-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/355df740-8958-4df9-a492-a76be0f9dd41

The open-access MAF lists 729 somatic variants for this specimen: 556 protein-altering or splice-affecting, 150 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 480, Silent 150, Nonsense Mutation 38, Splice Site 14, Intron 13, Frame Shift Del 13, RNA 8, Splice Region 4, Translation Start Site 3, Frame Shift Ins 2, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BBS12 | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as rs776730549, CM104181, COSV58561688; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CFTR | c.2679G>T p.G893= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs397508419, CS021743, COSV50070370, COSV50077065; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PHEX | c.263G>A p.W88* | Nonsense Mutation (SNP) | VAF 7/70 reads (10%) | catalogued as rs1569369653, COSV65077060, COSV65078620; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 27/59 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.1267C>A p.P423T (on ENST00000272895 / NM_173076.3; = p.P105T on NM_015657.3) | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV55966596, COSV55979772; called by muse, mutect2, varscan2
- ABCA5 | c.652del p.R218Efs*3 | Frame Shift Del (DEL) | VAF 19/107 reads (18%) | catalogued as COSV67017543; called by mutect2, pindel, varscan2
- ABCA8 | c.4440G>C p.K1480N | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.421); catalogued as COSV52206289; called by muse, mutect2, varscan2
- ABCB5 | c.1855C>T p.L619F (on ENST00000404938 / NM_001163941.2; = p.L174F on NM_178559.6) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as COSV51714250; called by muse, mutect2, varscan2
- AC011448.1 | c.394G>T p.G132W | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99364543; called by muse, mutect2, varscan2
- ACCS | c.1408+1G>T p.X470_splice | Splice Site (SNP) | VAF 7/93 reads (8%) | catalogued as COSV55459181; called by muse, mutect2
- ADAM11 | c.1976T>C p.M659T | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV52347801; called by muse, mutect2, varscan2
- ADAM11 | c.2051G>A p.R684Q | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs771811908, COSV52347819; called by muse, mutect2, varscan2
- ADAM33 | c.1541G>C p.C514S | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62935730; called by muse, mutect2, varscan2
- ADCY2 | c.452T>A p.L151Q | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57883995; called by muse, mutect2, varscan2
- ADGRE5 | c.1230G>T p.L410F (on ENST00000242786 / NM_078481.4; = p.L317F on NM_001784.5) | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.334); catalogued as COSV54412745; called by muse, mutect2, varscan2
- ADGRG4 | c.4925C>A p.P1642H | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV99795130; called by muse, mutect2, varscan2
- ADH1A | c.146C>A p.T49K | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV52924313, COSV52925495; called by muse, mutect2, varscan2
- AGK | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62595142; called by muse, mutect2
- AHNAK | c.13192A>T p.K4398* | Nonsense Mutation (SNP) | VAF 45/348 reads (13%) | catalogued as COSV57221041; called by muse, mutect2, varscan2
- AKR1C4 | c.197G>C p.R66P | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV54122178, COSV54124219; called by muse, mutect2
- ALG10 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 83/289 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56793087; called by muse, mutect2, varscan2
- ALG10 | c.994G>A p.V332I | Missense Mutation (SNP) | VAF 41/246 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV56793097; called by muse, mutect2, varscan2
- AMY2B | c.298A>G p.R100G | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63716082; called by muse, mutect2, varscan2
- ANKRD26 | c.4411G>A p.E1471K | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV101063250, COSV65776607; called by muse, mutect2
- ANKRD30A | c.3714T>A p.D1238E (on ENST00000611781; = p.D1182E on NM_052997.2) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.112); catalogued as COSV64614987; called by muse, mutect2, varscan2
- ANKRD7 | c.361A>T p.R121W | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.413); catalogued as COSV54555581; called by muse, mutect2
- ANKRD7 | c.363G>T p.R121S | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV54555592; called by muse, mutect2
- ANKS1B | c.1419G>T p.R473S | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as COSV61361626; called by muse, mutect2, varscan2
- ANO4 | c.2786A>G p.Y929C (on ENST00000392977 / NM_001286615.2; = p.Y894C on NM_178826.4) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54603578; called by muse, mutect2, varscan2
- AP3B2 | c.3263A>T p.Q1088L (on ENST00000261722; = p.Q1082L on NM_004644.5) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as COSV55611522; called by mutect2, varscan2
- APOB | c.4839C>A p.S1613R | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV51942860; called by muse, mutect2, varscan2
- APPBP2 | c.792G>T p.K264N | Missense Mutation (SNP) | VAF 31/251 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV50027802; called by muse, mutect2, varscan2
- ARHGEF15 | c.2123G>T p.R708L | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.489); catalogued as COSV62725756, COSV62726728; called by muse, mutect2, varscan2
- ARHGEF26 | c.587A>T p.K196M | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); catalogued as COSV100726486; called by muse, mutect2, varscan2
- ARMC7 | c.83A>T p.Q28L | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV99822609; called by muse, mutect2, varscan2
- ARPP21 | c.2031A>T p.A677= | Splice Region (SNP) | VAF 6/106 reads (6%) | catalogued as COSV51802266, COSV51802368; called by muse, mutect2
- ASB13 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63091373; called by muse, mutect2, varscan2
- ASPM | c.3518A>C p.Q1173P | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV54133383; called by muse, mutect2, varscan2
- ASTN1 | c.3445G>T p.D1149Y | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62500465; called by muse, mutect2, varscan2
- ATP1A3 | c.676G>T p.E226* (on ENST00000545399 / NM_001256214.2; = p.E213* on NM_152296.5) | Nonsense Mutation (SNP) | VAF 30/106 reads (28%) | catalogued as COSV57489235; called by muse, mutect2, varscan2
- ATP5F1C | c.25G>T p.G9W | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.866); catalogued as COSV59622203; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1702A>G p.R568G | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs1026320773, COSV59477746; called by muse, mutect2, varscan2
- ATR | c.6443G>A p.R2148Q | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1470834016, COSV63385063; called by muse, mutect2
- BACE1 | c.708C>G p.I236M | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV57285503; called by muse, mutect2
- BIN2 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs542179917, COSV57206564, COSV99909345; called by muse, mutect2, varscan2
- BPIFB4 | c.170-2A>T p.X57_splice | Splice Site (SNP) | VAF 17/154 reads (11%) | catalogued as COSV64951665; called by muse, mutect2, varscan2
- BRCA1 | c.4049G>C p.G1350A | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV58793957; called by muse, mutect2, varscan2
- BRINP3 | c.723A>T p.Q241H | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV66531097; called by muse, mutect2
- BTBD11 | c.2002C>A p.L668I (on ENST00000280758 / NM_001018072.2; = p.L205I on NM_001017523.2) | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV55029463; called by muse, mutect2, varscan2
- BTNL3 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750437240, COSV61565243; called by muse, mutect2, varscan2
- C2orf16 | c.3811C>G p.Q1271E | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs1341119613, COSV62676854; called by muse, mutect2, varscan2
- CACNA1B | c.1852C>A p.L618M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV99496570; called by muse, mutect2, varscan2
- CACNA1E | c.6253C>G p.R2085G (on ENST00000367573 / NM_001205293.3; = p.R2042G on NM_000721.4) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV62404814, COSV62428914; called by muse, mutect2, varscan2
- CACNG5 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50056946; called by muse, mutect2, varscan2
- CAD | c.1033G>T p.D345Y | Missense Mutation (SNP) | VAF 76/339 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1207287375, COSV53028963; called by muse, mutect2, varscan2
- CALCRL | c.256C>A p.Q86K | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.213); catalogued as COSV66476027; called by muse, mutect2
- CAMK1D | c.973G>C p.G325R | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66615353; called by muse, mutect2, varscan2
- CAMSAP2 | c.1864G>T p.G622* (on ENST00000236925 / NM_001297707.2; = p.G611* on NM_203459.3) | Nonsense Mutation (SNP) | VAF 33/146 reads (23%) | catalogued as COSV52673638; called by muse, mutect2, varscan2
- CASP1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 24/203 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV100782753, COSV62057506; called by muse, mutect2, varscan2
- CASP10 | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV53779378; called by muse, mutect2, varscan2
- CASP10 | c.1360G>C p.E454Q (on ENST00000272879 / NM_032974.5; = p.E411Q on NM_001230.5) | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.536); catalogued as COSV53779387; called by muse, mutect2, varscan2
- CATSPERE | c.970G>T p.D324Y | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV63679690; called by muse, mutect2
- CC2D1A | c.1872G>T p.K624N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV58784692; called by muse, mutect2, varscan2
- CC2D2B | c.503T>A p.L168* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as COSV60358479; called by muse, mutect2, varscan2
- CCDC38 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 29/160 reads (18%) | catalogued as COSV60183805; called by muse, varscan2
- CCDC38 | c.460C>A p.L154I | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60182179, COSV60183811; called by muse, varscan2
- CCER1 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1386474051, COSV62647391; called by muse, mutect2
- CCKBR | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.401); catalogued as COSV58103122; called by muse, mutect2
- CD109 | c.1206G>T p.W402C | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.095); catalogued as COSV54652792; called by muse, mutect2, varscan2
- CD93 | c.1529C>A p.P510H | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1163522353, COSV55666769, COSV99849703; called by muse, varscan2
- CDH10 | c.1834G>T p.G612W | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369284486, COSV52594290; called by muse, mutect2, varscan2
- CDH10 | c.1412C>A p.T471K | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as COSV52587720; called by muse, mutect2, varscan2
- CDH12 | c.1379T>C p.I460T | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.089); catalogued as COSV66423031; called by muse, mutect2, varscan2
- CDH18 | c.2026T>A p.L676M | Missense Mutation (SNP) | VAF 17/205 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.732); catalogued as COSV56939112; called by muse, mutect2
- CDH20 | c.1022T>C p.L341P | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53011701, COSV53013267; called by muse, mutect2, varscan2
- CDH23 | c.2791G>T p.V931L | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.729); catalogued as COSV54942321; called by muse, mutect2
- CDH26 | c.545A>T p.Q182L | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV54849946; called by muse, mutect2
- CDH8 | c.938A>T p.Y313F | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as COSV54881267; called by muse, mutect2, varscan2
- CDH9 | c.1981G>T p.D661Y | Missense Mutation (SNP) | VAF 57/336 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50250776, COSV50334530; called by muse, varscan2
- CDKL4 | c.668G>T p.R223I | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV66509422; called by muse, mutect2, varscan2
- CDYL | c.160G>C p.G54R | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV61042948; called by muse, mutect2, varscan2
- CEP128 | c.2026G>T p.D676Y | Missense Mutation (SNP) | VAF 26/235 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV55376987; called by muse, mutect2, varscan2
- CEP63 | c.369G>T p.R123S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV59677513; called by muse, mutect2, varscan2
- CFH | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 68/216 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100661393, COSV62778172; called by muse, mutect2, varscan2
- CHD4 | c.1064-7G>C | Splice Region (SNP) | VAF 8/88 reads (9%) | catalogued as COSV58905106; called by muse, mutect2
- CHIA | c.784G>A p.V262I (on ENST00000343320; = p.V154I on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.155); catalogued as rs367730751; called by muse, mutect2
- CHL1 | c.3335C>G p.S1112* (on ENST00000397491 / NM_001253387.1; = p.S1128* on NM_006614.4) | Nonsense Mutation (SNP) | VAF 11/82 reads (13%) | catalogued as COSV56597880; called by muse, mutect2, varscan2
- CHRNA6 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99373161; called by muse, mutect2, varscan2
- CLASP1 | c.4335G>T p.M1445I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.338); catalogued as COSV55329935; called by muse, mutect2
- CLEC10A | c.817G>C p.G273R (on ENST00000254868 / NM_182906.4; = p.G249R on NM_006344.4) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54701800; called by muse, mutect2, varscan2
- CMKLR1 | c.1103G>T p.R368M (on ENST00000312143 / NM_001142344.2; = p.R366M on NM_004072.3) | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV56437016; called by muse, mutect2, varscan2
- CMPK2 | c.1244A>T p.Q415L | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.258); catalogued as COSV56775376; called by muse, mutect2, varscan2
- CNGB3 | c.1424T>A p.V475E | Missense Mutation (SNP) | VAF 31/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV60693260; called by muse, mutect2, varscan2
- CNTN6 | c.2280G>C p.R760S | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV100610965, COSV63179635; called by muse, mutect2, varscan2
- COL6A3 | c.5120A>G p.N1707S | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV55097689; called by muse, mutect2, varscan2
- COL6A6 | c.1093C>A p.L365M | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV62030269; called by muse, mutect2, varscan2
- CORO6 | c.512A>T p.D171V | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV61471440; called by muse, mutect2, varscan2
- CPB1 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.182); catalogued as COSV51574894, COSV51576182; called by mutect2, varscan2
- CR1L | c.1649A>C p.H550P | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV54328605; called by muse, mutect2
- CRISPLD1 | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51550718; called by muse, mutect2
- CRNN | c.1325G>T p.W442L | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55121673; called by muse, mutect2, varscan2
- CRYBG3 | c.7201T>C p.C2401R | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as rs1381310579, COSV51713848; called by muse, mutect2
- CSMD2 | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV53931745; called by muse, mutect2, varscan2
- CSMD3 | c.3968C>A p.T1323N (on ENST00000297405 / NM_001363185.1; = p.T1219N on NM_052900.3) | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV52239289, COSV99837521; called by muse, varscan2
- CT45A10 | c.341C>A p.S114Y | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.176); catalogued as COSV65921284, COSV65921344; called by muse, mutect2
- CTLA4 | c.503C>A p.A168E | Missense Mutation (SNP) | VAF 11/273 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV55592690; called by muse, mutect2
- CTNNA3 | c.807G>T p.Q269H | Missense Mutation (SNP) | VAF 33/365 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.31); catalogued as COSV65601719; called by muse, mutect2
- CWH43 | c.1466T>C p.F489S | Missense Mutation (SNP) | VAF 33/240 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as COSV56940946; called by muse, mutect2, varscan2
- CXorf21 | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 27/54 reads (50%) | catalogued as COSV100973258; called by muse, mutect2, varscan2
- CYP2F1 | c.173T>A p.L58Q | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV58528178; called by muse, mutect2, varscan2
- CYP4F12 | c.194G>T p.G65V | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV61175038; called by muse, mutect2
- CYP4F8 | c.1078G>T p.E360* | Nonsense Mutation (SNP) | VAF 19/98 reads (19%) | catalogued as COSV57854602; called by muse, mutect2, varscan2
- DAB2 | c.1036C>A p.Q346K | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV100297913; called by muse, mutect2
- DAO | c.915C>A p.V305= | Splice Region (SNP) | VAF 18/85 reads (21%) | catalogued as COSV57323403; called by muse, mutect2, varscan2
- DCAF17 | c.1246G>T p.D416Y | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV59830709; called by muse, mutect2, varscan2
- DCAF8 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV58784801; called by muse, mutect2, varscan2
- DCAF8L1 | c.1621G>T p.D541Y | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV101491416, COSV71595388; called by muse, mutect2, varscan2
- DDX50 | c.1585G>T p.D529Y | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV65292828; called by muse, mutect2, varscan2
- DIDO1 | c.4225G>T p.E1409* | Nonsense Mutation (SNP) | VAF 18/180 reads (10%) | catalogued as COSV56623373, COSV56627673; called by muse, mutect2
- DMRT1 | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.886); catalogued as COSV66522660; called by muse, mutect2, varscan2
- DMRT3 | c.1066G>T p.G356W | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV51906306; called by muse, mutect2, varscan2
- DNAAF6 | c.202C>A p.P68T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60496305; called by muse, mutect2
- DNAH7 | c.6164G>T p.G2055V | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56773871; called by muse, mutect2, varscan2
- DNAJB4 | c.547C>G p.R183G | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs141666453, COSV66131887; called by muse, mutect2, varscan2
- DNAJC6 | c.752G>T p.C251F | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54778095; called by muse, mutect2, varscan2
- DNM1L | c.1418G>T p.R473L | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56775771, COSV99846474; called by muse, mutect2, varscan2
- DOCK2 | c.653C>A p.S218Y | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.915); catalogued as COSV56971078; called by muse, mutect2, varscan2
- DOCK2 | c.800C>G p.P267R | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV56971090; called by muse, mutect2, varscan2
- DRAM2 | c.394G>T p.G132C | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54415879, COSV54415930; called by muse, mutect2, varscan2
- DSCAM | c.4646G>T p.R1549L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV68030991; called by muse, mutect2, varscan2
- DUS2 | c.1027G>A p.G343R | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV62709139; called by muse, mutect2, varscan2
- DYNC1H1 | c.5716G>C p.G1906R | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64139100; called by muse, mutect2, varscan2
- EDNRB | c.1415A>T p.N472I (on ENST00000377211 / NM_001201397.1; = p.N382I on NM_000115.5) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57525303; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1346G>T p.R449L (on ENST00000361735 / NM_015935.5; = p.R363L on NM_014955.3) | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV62283471; called by muse, mutect2, varscan2
- EFNB2 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.231); catalogued as COSV99808671; called by muse, mutect2
- EIF4B | c.1486C>G p.Q496E | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.345); catalogued as COSV50405034; called by muse, mutect2
- EME2 | c.1114G>C p.D372H | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.331); catalogued as COSV99456886; called by muse, mutect2, varscan2
- ENPP6 | c.751A>G p.K251E | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.682); catalogued as COSV57069749; called by muse, mutect2, varscan2
- EPB41L2 | c.2747G>T p.G916V | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as COSV100440503; called by muse, mutect2
- EPHA6 | c.2482G>T p.G828* (on ENST00000389672 / NM_001080448.3; = p.G220* on NM_173655.4) | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as COSV67561087, COSV67581469; called by muse, mutect2, varscan2
- EPHA7 | c.1694G>T p.G565V | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.052); catalogued as COSV65187176; called by muse, mutect2, varscan2
- EPHB1 | c.1631G>T p.G544V | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.722); catalogued as COSV67665334; called by muse, mutect2, varscan2
- EPHB2 | c.1246G>T p.D416Y | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV65863980, COSV65866573; called by muse, mutect2, varscan2
- EREG | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1560600580, COSV55261886; called by muse, mutect2, varscan2
- ERMAP | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); catalogued as COSV60274944; called by muse, mutect2
- FAM117A | c.802G>T p.A268S | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99544609; called by muse, mutect2, varscan2
- FAM217B | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as COSV100674488; called by muse, mutect2
- FAM47C | c.1184C>A p.P395H | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as COSV63728368; called by muse, mutect2, varscan2
- FAM83B | c.146A>T p.Q49L | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV60924157; called by muse, mutect2
- FAM83B | c.724G>T p.G242C | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60924164; called by muse, mutect2, varscan2
- FAM90A1 | c.964G>A p.G322R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.982); catalogued as COSV56713245; called by muse, mutect2, varscan2
- FAT3 | c.3797G>A p.R1266H | Missense Mutation (SNP) | VAF 31/255 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759492943, COSV53101299, COSV53168867; called by muse, mutect2, varscan2
- FBXO38 | c.2204G>T p.G735V | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.159); catalogued as COSV57025951, COSV57029382; called by muse, mutect2, varscan2
- FCGR3A | c.-44-1G>T | Splice Site (SNP) | VAF 10/72 reads (14%) | catalogued as COSV63460017; called by muse, mutect2, varscan2
- FCGR3B | c.439G>C p.D147H | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV54209245, COSV54210810; called by muse, varscan2
- FERD3L | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV51763396; called by muse, mutect2, varscan2
- FGB | c.949G>T p.G317C | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57418891; called by muse, mutect2, varscan2
- FIGNL1 | c.1214G>T p.G405V | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63553780; called by muse, mutect2, varscan2
- FLG | c.6601G>T p.D2201Y | Missense Mutation (SNP) | VAF 73/700 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV64238223, COSV64244527; called by muse, mutect2, varscan2
- FLG | c.2243C>G p.T748S | Missense Mutation (SNP) | VAF 124/846 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201522026, COSV64246567; called by muse, mutect2, varscan2
- FLG2 | c.5963C>A p.S1988Y | Missense Mutation (SNP) | VAF 157/589 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as rs1358915640, COSV66170476; called by muse, mutect2, varscan2
- FLI1 | c.542T>G p.L181R | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV55646170; called by muse, mutect2, varscan2
- FLT4 | c.655C>A p.P219T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV56109439, COSV56114697; called by muse, mutect2, varscan2
- FMO3 | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63007843; called by muse, mutect2, varscan2
- FNBP4 | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV55450200; called by muse, mutect2
- FOXC2 | c.261C>A p.N87K | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV100234218; called by muse, mutect2
- FSIP2 | c.18898C>A p.P6300T | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100554757; called by muse, mutect2
- FZD1 | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55312014; called by muse, mutect2, varscan2
- GABRA3 | c.1357A>C p.S453R | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV64801833; called by muse, mutect2, varscan2
- GABRG2 | c.802G>T p.E268* (on ENST00000361925 / NM_001375343.1; = p.E228* on NM_000816.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV62719879; called by muse, mutect2, varscan2
- GALNT13 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV67228617; called by muse, mutect2, varscan2
- GALNT13 | c.418A>T p.N140Y | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV67216149, COSV67228622; called by muse, mutect2, varscan2
- GALNTL6 | c.133C>A p.Q45K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV101550691, COSV72552914; called by muse, varscan2
- GBF1 | c.3052C>T p.H1018Y (on ENST00000369983 / NM_001377137.1; = p.H1017Y on NM_004193.3) | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs1279016956, COSV64146756; called by muse, mutect2, varscan2
- GBP6 | c.1468+1G>A p.X490_splice | Splice Site (SNP) | VAF 12/146 reads (8%) | catalogued as COSV65011981; called by muse, mutect2
- GCC1 | c.1322G>T p.R441M | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV58463088; called by muse, mutect2, varscan2
- GLS | c.1415T>G p.F472C | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57843756; called by muse, mutect2, varscan2
- GLT8D2 | c.178G>T p.G60W | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV100673964, COSV62562404; called by muse, mutect2, varscan2
- GOLGB1 | c.2054A>T p.E685V | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV61467855; called by muse, mutect2, varscan2
- GPR101 | c.185T>A p.L62Q | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99981360; called by muse, mutect2, varscan2
- GPR32 | c.555G>T p.W185C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.467); catalogued as COSV54515030; called by mutect2, varscan2
- GRPEL1 | c.604C>A p.H202N | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as COSV99380605; called by muse, mutect2, varscan2
- GTDC1 | c.1080G>T p.M360I | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.139); catalogued as COSV53999604; called by muse, mutect2, varscan2
- GTF2A1 | c.155A>T p.Q52L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV53337698; called by muse, mutect2, varscan2
- GTF3C4 | c.428A>C p.Q143P | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64645673; called by muse, mutect2
- HEATR3 | c.1209G>T p.E403D | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV53530458; called by muse, mutect2, varscan2
- HEXIM1 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100203442; called by muse, mutect2, varscan2
- HIRA | c.989C>G p.S330C | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV54276966; called by muse, mutect2
- HMBS | c.166A>G p.M56V | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs761130805, COSV53829261; called by muse, mutect2, varscan2
- HMGCR | c.809A>T p.H270L | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as COSV99843168; called by muse, mutect2, varscan2
- HNRNPA3 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.725); catalogued as COSV66820995; called by muse, mutect2
- IFNA7 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV53331703, COSV53332099; called by muse, mutect2
- IFNB1 | c.107T>C p.F36S | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV101207794; called by muse, mutect2
- IGHV4-31 | c.245C>A p.P82Q | Missense Mutation (SNP) | VAF 60/521 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); catalogued as rs1357987078; called by mutect2, varscan2
- IKBKE | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1452780177, COSV65623508; called by muse, mutect2, varscan2
- IL12RB2 | c.1078T>C p.Y360H | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52024844; called by muse, mutect2, varscan2
- IMPACT | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs764166835, COSV52422719; called by muse, mutect2, varscan2
- IRF2BP2 | c.1606C>A p.Q536K | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.182); catalogued as COSV100784280; called by muse, mutect2, varscan2
- ITGAD | c.2404G>T p.V802L | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.152); catalogued as COSV66758805; called by muse, mutect2, varscan2
- JADE3 | c.94A>G p.K32E | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.155); catalogued as rs192950306, COSV54464257, COSV54468255; called by muse, mutect2, varscan2
- JHY | c.1510G>T p.V504L | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV57077402; called by muse, mutect2, varscan2
- KAT6B | c.4585G>A p.E1529K | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); catalogued as COSV54750610; called by muse, mutect2, varscan2
- KCND2 | c.798C>A p.D266E | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58567542, COSV58590964; called by muse, mutect2, varscan2
- KCNH5 | c.1742G>T p.G581V | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59766794; called by muse, mutect2, varscan2
- KCNH8 | c.2167G>T p.E723* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as COSV60469470; called by muse, mutect2, varscan2
- KCNJ12 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV59169613; called by muse, mutect2, varscan2
- KCNJ16 | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 11/272 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.16); catalogued as COSV52256402, COSV99388132; called by muse, mutect2
- KCNN4 | c.892G>T p.V298L | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs968674510, COSV53456239, COSV53456739; called by muse, mutect2, varscan2
- KCNT2 | c.3014C>A p.S1005* | Nonsense Mutation (SNP) | VAF 31/137 reads (23%) | catalogued as COSV54091773; called by muse, mutect2, varscan2
- KCNT2 | c.2372G>T p.G791V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54091787; called by muse, mutect2, varscan2
- KDM2B | c.3544T>A p.W1182R | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65642811; called by muse, mutect2
- KIAA0232 | c.3931G>A p.G1311R | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.084); catalogued as COSV56927058; called by muse, mutect2, varscan2
- KIAA0895 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 7/57 reads (12%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV51712107; called by muse, mutect2, varscan2
- KIF18B | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV59274624; called by muse, mutect2, varscan2
- KIF21B | c.3092G>T p.R1031L | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59761168, COSV59764643; called by muse, mutect2, varscan2
- KMO | c.872C>A p.S291Y | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.331); catalogued as COSV63806517; called by muse, mutect2, varscan2
- KMT2C | c.6148C>T p.P2050S | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs1334577127, COSV51455083; called by muse, mutect2, varscan2
- KRT2 | c.1234C>T p.H412Y | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV59011428; called by muse, mutect2, varscan2
- KRT38 | c.340C>G p.R114G | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV55845954, COSV55846677; called by muse, mutect2, varscan2
- KRT4 | c.1033G>T p.G345C | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53408478; called by muse, varscan2
- KRTAP10-3 | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 96/270 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV100552801; called by muse, mutect2, varscan2
- KRTAP12-2 | c.194G>C p.C65S | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.235); catalogued as COSV100552803; called by muse, mutect2, varscan2
- KRTAP9-3 | c.314G>C p.C105S | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as COSV101370139; called by muse, mutect2
- LAMA3 | c.4553G>T p.W1518L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58072918; called by muse, mutect2, varscan2
- LATS1 | c.1412A>G p.N471S | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53594639; called by muse, mutect2, varscan2
- LCMT2 | c.894G>C p.E298D | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59790968; called by muse, mutect2, varscan2
- LGI1 | c.549G>T p.W183C | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65058628; called by muse, mutect2
- LGI2 | c.954A>G p.I318M | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV66123389; called by muse, mutect2
- LIMA1 | c.1792C>G p.Q598E | Missense Mutation (SNP) | VAF 40/345 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV57966745; called by muse, mutect2, varscan2
- LIMA1 | c.1543C>G p.Q515E | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.047); catalogued as rs1263000294, COSV57966750; called by muse, mutect2, varscan2
- LIN28B | c.97C>A p.H33N | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.877); catalogued as COSV61496180; called by muse, mutect2, varscan2
- LRGUK | c.355G>T p.G119W | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53640364; called by muse, mutect2, varscan2
- LRP1B | c.9715C>A p.R3239S | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67246960, COSV67260041; called by muse, mutect2
- LRP1B | c.2430G>T p.L810F | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV67230208, COSV67232465, COSV67246966; called by muse, mutect2, varscan2
- LRRC32 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 9/46 reads (20%) | catalogued as COSV52633096, COSV52633999; called by muse, mutect2, varscan2
- LRRIQ4 | c.68T>A p.V23D | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV61619633; called by muse, mutect2
- LRRK2 | c.4806G>T p.W1602C | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54160643; called by muse, mutect2, varscan2
- LYST | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV67710054; called by muse, mutect2, varscan2
- MAP1B | c.6491C>A p.P2164Q | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57096929, COSV57102339; called by muse, mutect2, varscan2
- MARCHF1 | c.176C>A p.T59K (on ENST00000274056; = p.T42K on NM_017923.4) | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.759); catalogued as COSV56822204; called by muse, mutect2
- MATN4 | c.1303C>T p.R435C (on ENST00000372754; = p.R394C on NM_003833.4) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | PolyPhen probably damaging (1); catalogued as COSV61352739; called by muse, mutect2, varscan2
- MCM4 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV50626633; called by muse, mutect2, varscan2
- MDFIC | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 15/280 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV57565424; called by muse, mutect2
- MED1 | c.413T>C p.L138P | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56126767; called by muse, mutect2, varscan2
- MED12L | c.227T>C p.I76T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56386393; called by muse, mutect2, varscan2
- MED13L | c.4968G>T p.R1656S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as COSV56124363; called by muse, mutect2, varscan2
- MED13L | c.283G>C p.V95L | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.122); catalogued as COSV56124368; called by muse, mutect2, varscan2
- METTL9 | c.751+1G>T p.X251_splice | Splice Site (SNP) | VAF 13/77 reads (17%) | catalogued as COSV100820538; called by muse, mutect2, varscan2
- MICAL2 | c.2749C>G p.P917A | Missense Mutation (SNP) | VAF 46/299 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV56322675; called by muse, mutect2, varscan2
- MKI67 | c.3812G>A p.R1271K | Missense Mutation (SNP) | VAF 16/249 reads (6%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.579); catalogued as rs765282623, COSV64075463; called by muse, mutect2
- MLLT3 | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 69/266 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV63499337; called by muse, mutect2, varscan2
- MMP13 | c.850T>C p.C284R | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs782239802, COSV52824657; called by muse, mutect2
- MMRN1 | c.3065C>A p.T1022N | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV53339774; called by muse, mutect2, varscan2
- MPO | c.1537del p.D513Tfs*45 | Frame Shift Del (DEL) | VAF 23/178 reads (13%) | catalogued as COSV51861375; called by mutect2, pindel, varscan2
- MPPED2 | c.839C>A p.T280N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.063); catalogued as COSV63899667; called by muse, mutect2, varscan2
- MREG | c.158G>C p.W53S | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54374810; called by muse, mutect2
- MRO | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs756486124, COSV99839141, COSV99839521; called by muse, mutect2, varscan2
- MS4A14 | c.151C>A p.L51M | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55730723; called by muse, mutect2, varscan2
- MT2A | c.28G>T p.G10C | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99803167; called by muse, mutect2, varscan2
- MTMR8 | c.1039C>G p.Q347E | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV66395012; called by muse, varscan2
- MTMR9 | c.636G>T p.R212S | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV55313749; called by muse, mutect2, varscan2
- MXRA5 | c.6288C>A p.H2096Q | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.456); catalogued as COSV54232781, COSV54241748; called by muse, varscan2
- MYBPH | c.1315C>A p.L439I | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55143197; called by muse, mutect2
- MYF5 | c.707C>A p.T236N | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs757659254, COSV57355707, COSV57357088; called by muse, mutect2, varscan2
- MYH2 | c.2869A>T p.K957* | Nonsense Mutation (SNP) | VAF 87/291 reads (30%) | catalogued as COSV99819832; called by muse, mutect2, varscan2
- MYO18A | c.778G>T p.G260C | Missense Mutation (SNP) | VAF 80/239 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62869841; called by muse, mutect2, varscan2
- MYO3A | c.3245G>T p.R1082M | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as COSV56338595, COSV56351768; called by muse, mutect2, varscan2
- MYT1L | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 29/270 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.996); catalogued as COSV67725679; called by muse, mutect2, varscan2
- NAALAD2 | c.707G>T p.W236L | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV58963216; called by muse, mutect2, varscan2
- NALCN | c.4076C>A p.T1359N | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.147); catalogued as COSV51948548; called by muse, varscan2
- NALCN | c.2822G>T p.G941V | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51948556; called by muse, mutect2, varscan2
- NCS1 | c.261G>T p.Q87H | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.385); catalogued as COSV64963036; called by muse, mutect2, varscan2
- NDUFA8 | c.223A>T p.K75* | Nonsense Mutation (SNP) | VAF 9/104 reads (9%) | catalogued as COSV101056787; called by muse, mutect2
- NECAP1 | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.121); catalogued as COSV100331567; called by muse, mutect2, varscan2
- NF1 | c.7069G>T p.E2357* (on ENST00000358273 / NM_001042492.3; = p.E2336* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 23/93 reads (25%) | catalogued as CM013781, COSV62210223; called by muse, mutect2, varscan2
- NLRP4 | c.2510G>T p.C837F | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV56717689; called by muse, mutect2, varscan2
- NLRP5 | c.2071C>G p.L691V | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV66765948; called by muse, mutect2
- NOTCH2 | c.6314G>T p.R2105L | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV56680639, COSV56690102; called by muse, mutect2, varscan2
- NOX5 | c.325G>T p.V109L | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.007); catalogued as COSV52992179; called by muse, mutect2, varscan2
- NPY5R | c.1039G>T p.V347F | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.033); catalogued as COSV58452768; called by muse, mutect2, varscan2
- NR2E1 | c.965A>T p.Q322L | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV64562360; called by muse, mutect2, varscan2
- NRAP | c.935C>A p.P312Q | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV63492224; called by muse, mutect2
- NRDE2 | c.1558G>T p.E520* | Nonsense Mutation (SNP) | VAF 23/84 reads (27%) | catalogued as COSV62963872; called by muse, mutect2, varscan2
- NSUN3 | c.123-2A>T p.X41_splice | Splice Site (SNP) | VAF 10/45 reads (22%) | catalogued as COSV58936498; called by muse, mutect2
- NTRK1 | c.1670T>A p.F557Y | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100693301; called by muse, mutect2, varscan2
- NUP54 | c.125C>G p.S42C | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV53576371; called by muse, mutect2, varscan2
- OBSCN | c.12517G>T p.D4173Y | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV52795786; called by muse, mutect2, varscan2
- OR10C1 | c.334G>T p.E112* (on ENST00000622521; = p.E110* on NM_013941.3) | Nonsense Mutation (SNP) | VAF 22/92 reads (24%) | catalogued as COSV65823462; called by muse, mutect2, varscan2
- OR10G9 | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as COSV66686489; called by muse, varscan2
- OR10H4 | c.684G>C p.L228F | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV59062320; called by muse, mutect2
- OR10T2 | c.263C>A p.S88* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as COSV57782240; called by muse, mutect2, varscan2
- OR2AE1 | c.46G>T p.G16W | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100318296; called by muse, mutect2, varscan2
- OR2H1 | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 17/274 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV65811037; called by muse, mutect2
- OR2H1 | c.338T>A p.L113Q | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.539); catalogued as COSV65811043; called by muse, mutect2, varscan2
- OR2M7 | c.120G>T p.M40I | Missense Mutation (SNP) | VAF 80/342 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV58738972, COSV58739697; called by mutect2, varscan2
- OR2T11 | c.509G>T p.S170I | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV58186498; called by muse, mutect2, varscan2
- OR2T33 | c.434C>A p.S145* | Nonsense Mutation (SNP) | VAF 29/201 reads (14%) | catalogued as COSV58815638, COSV58816435; called by muse, mutect2, varscan2
- OR2T34 | c.35C>T p.T12I | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV60901086; called by muse, mutect2
- OR4A16 | c.380C>A p.P127Q | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV59044107; called by muse, mutect2, varscan2
- OR4D6 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV55659201, COSV55660263; called by muse, mutect2, varscan2
- OR4K13 | c.290G>C p.C97S | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59860096; called by muse, mutect2, varscan2
- OR51B4 | c.749T>A p.I250N | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100971109; called by mutect2, varscan2
- OR51I1 | c.424C>A p.R142S | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV66508497; called by muse, mutect2, varscan2
- OR51M1 | c.612C>G p.I204M | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as COSV100150176, COSV60784966; called by muse, mutect2
- OR51V1 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58315726; called by muse, mutect2, varscan2
- OR52B4 | c.399G>T p.R133S | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV68769208; called by muse, mutect2, varscan2
- OR52N1 | c.371A>T p.H124L | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV57693682; called by muse, mutect2
- OR5B21 | c.155A>G p.H52R | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV64482086; called by muse, mutect2, varscan2
- OR5I1 | c.691C>A p.R231S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.282); catalogued as COSV100041338, COSV56886847; called by muse, mutect2, varscan2
- OR5K4 | c.85G>T p.V29L | Missense Mutation (SNP) | VAF 39/296 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1161252268, COSV100721330; called by muse, mutect2, varscan2
- OR6K3 | c.433C>A p.P145T (on ENST00000368146; = p.P129T on NM_001005327.2) | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63746022; called by muse, mutect2
- OR6Q1 | c.936C>G p.N312K | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1208045554, COSV100109456, COSV56933747; called by muse, mutect2
- OR7A10 | c.476A>T p.Q159L | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.935); catalogued as COSV50166534; called by muse, mutect2, varscan2
- PALD1 | c.1972G>A p.V658M | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as rs768998753, COSV54976067; called by muse, varscan2
- PAPPA2 | c.425G>C p.G142A | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.027); catalogued as COSV62781678; called by muse, mutect2, varscan2
- PAPPA2 | c.3561C>A p.Y1187* | Nonsense Mutation (SNP) | VAF 40/174 reads (23%) | catalogued as COSV62803547; called by muse, mutect2, varscan2
- PARP6 | c.1801G>T p.G601C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53004014; called by muse, mutect2, varscan2
- PCDH11X | c.347C>A p.P116Q | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs750562367, COSV53462647, COSV53483839; called by muse, mutect2, varscan2
- PCDH18 | c.1778G>T p.G593V | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.242); catalogued as COSV61269980; called by muse, mutect2
- PCDHA10 | c.1441G>T p.A481S | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.235); catalogued as COSV56474773, COSV56522919; called by muse, varscan2
- PCDHA11 | c.1495G>T p.G499C | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56522949; called by muse, mutect2, varscan2
- PCDHA12 | c.1458G>C p.K486N | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.585); catalogued as COSV56522967; called by muse, mutect2
- PCDHB11 | c.29A>T p.Q10L | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV53381257, COSV99504109; called by muse, mutect2, varscan2
- PCF11 | c.3436C>G p.P1146A | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.607); catalogued as COSV53534509; called by muse, mutect2, varscan2
- PCYT1A | c.584A>G p.Q195R | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as rs187437949, COSV53058652; called by muse, mutect2, varscan2
- PDE10A | c.1670T>A p.L557Q | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63101112; called by muse, mutect2, varscan2
- PDHA1 | c.832-2A>T p.X278_splice | Splice Site (SNP) | VAF 85/174 reads (49%) | catalogued as COSV58833839; called by muse, mutect2, varscan2
- PDILT | c.1292G>A p.G431D | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56703171; called by muse, mutect2, varscan2
- PDYN | c.695G>T p.R232L | Missense Mutation (SNP) | VAF 19/210 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774175877, COSV54101517, COSV54102525; called by muse, mutect2
- PEG3 | c.3665G>T p.G1222V | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV55639378; called by muse, mutect2, varscan2
- PGM2 | c.1144A>T p.K382* | Nonsense Mutation (SNP) | VAF 12/188 reads (6%) | catalogued as COSV67939201; called by muse, mutect2
- PGM2L1 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV53348053; called by muse, mutect2
- PGM5 | c.707C>A p.P236H | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67164456; called by muse, mutect2
- PHLDA3 | c.245A>G p.E82G | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100943603; called by muse, mutect2
- PHLDB2 | c.728G>T p.S243I | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV67313459; called by muse, mutect2, varscan2
- PHLDB2 | c.3169-1G>T p.X1057_splice (on ENST00000393925 / NM_001134439.2; = p.X1014_splice on NM_145753.2) | Splice Site (SNP) | VAF 3/32 reads (9%) | catalogued as COSV67313466; called by muse, mutect2
- PHLPP1 | c.1822G>T p.G608* | Nonsense Mutation (SNP) | VAF 34/94 reads (36%) | catalogued as COSV53032808; called by muse, mutect2, varscan2
- PHRF1 | c.1937C>T p.A646V (on ENST00000264555 / NM_001286581.2; = p.A645V on NM_020901.4) | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as rs756569593, COSV52753980; called by muse, mutect2
- PI16 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV65320122; called by muse, mutect2, varscan2
- PKP4 | c.2323G>C p.E775Q | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.072); catalogued as COSV61579360; called by muse, mutect2, varscan2
- PLCB4 | c.1065-1G>T p.X355_splice | Splice Site (SNP) | VAF 49/111 reads (44%) | catalogued as COSV53808303; called by muse, mutect2, varscan2
- PLD4 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.384); catalogued as rs375089731, COSV101190480; called by muse, mutect2, varscan2
- PLD5 | c.1315C>G p.R439G (on ENST00000442594; = p.R377G on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV59143381, COSV59155873; called by muse, mutect2
- PLEK | c.235C>A p.H79N | Missense Mutation (SNP) | VAF 34/183 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); catalogued as COSV52252294, COSV52252768; called by muse, mutect2, varscan2
- PLPP4 | c.125C>A p.P42H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.846); catalogued as COSV100956324, COSV64828637; called by muse, mutect2, varscan2
- POU3F4 | c.803G>C p.S268T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.18); catalogued as COSV64540079; called by muse, mutect2, varscan2
- PPM1L | c.593C>A p.A198D | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99861534; called by muse, mutect2, varscan2
- PPP1R13B | c.457-2A>T p.X153_splice | Splice Site (SNP) | VAF 14/103 reads (14%) | catalogued as COSV52453678; called by muse, mutect2, varscan2
- PPP1R3A | c.3161T>C p.L1054P | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV52886738; called by muse, mutect2, varscan2
- PPRC1 | c.3963G>C p.W1321C | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53386925; called by muse, mutect2, varscan2
- PRAMEF1 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 42/263 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60012251; called by muse, mutect2, varscan2
- PRCP | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV57289927; called by muse, mutect2, varscan2
- PREX1 | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV64253951; called by muse, mutect2, varscan2
- PRKCI | c.1188C>A p.D396E | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55516426, COSV55518976, COSV99855853; called by muse, mutect2, varscan2
- PRMT8 | c.1068del p.T357Pfs*4 | Frame Shift Del (DEL) | VAF 43/146 reads (29%) | catalogued as COSV54212132, COSV54215267; called by mutect2, pindel, varscan2
- PROS1 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62399039; called by muse, mutect2, varscan2
- PRSS38 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64540955; called by muse, varscan2
- PRSS38 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64539727, COSV64540813; called by muse, varscan2
- PSG2 | c.777G>T p.L259F | Missense Mutation (SNP) | VAF 62/294 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV61545805; called by muse, mutect2, varscan2
- PSG6 | c.573G>C p.R191S | Missense Mutation (SNP) | VAF 35/432 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs1058688, COSV51831805, COSV99414322; called by muse, mutect2
- PSG9 | c.724C>A p.P242T | Missense Mutation (SNP) | VAF 43/375 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV52486368, COSV52488592; called by muse, mutect2, varscan2
- PSME4 | c.3766A>G p.I1256V | Missense Mutation (SNP) | VAF 35/281 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs139295214; called by muse, mutect2, varscan2
- PTGS2 | c.1496G>T p.R499L | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.211); catalogued as rs200408009, COSV66570591; called by muse, mutect2, varscan2
- PTH2R | c.433T>A p.Y145N | Missense Mutation (SNP) | VAF 63/276 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.487); catalogued as COSV55917816; called by muse, mutect2, varscan2
- PTPN5 | c.856C>A p.Q286K | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV62127153; called by muse, mutect2
- PTPRB | c.5488C>A p.L1830M | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV54242322, COSV54246377; called by muse, mutect2, varscan2
- PTPRH | c.682T>A p.W228R | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54747526; called by muse, mutect2, varscan2
- PTPRN | c.1280C>A p.P427H | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as COSV55346664; called by muse, mutect2, varscan2
- PTPRS | c.5822G>A p.G1941E | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53627326; called by muse, mutect2, varscan2
- PTRH1 | c.-1320-2A>T | Splice Site (SNP) | VAF 5/75 reads (7%) | catalogued as COSV58853632; called by muse, mutect2
- RABGAP1L | c.1073A>G p.Y358C | Missense Mutation (SNP) | VAF 7/192 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV52308551; called by muse, mutect2
- RAP1GDS1 | c.412G>A p.D138N (on ENST00000408927 / NM_001100427.2; = p.D139N on NM_021159.5) | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as COSV52789215; called by muse, mutect2, varscan2
- RAP1GDS1 | c.1265T>G p.L422R (on ENST00000408927 / NM_001100427.2; = p.L423R on NM_021159.5) | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV52789226; called by muse, mutect2, varscan2
- RBM10 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 24/49 reads (49%) | catalogued as COSV61309929, COSV61312978; called by muse, mutect2, varscan2
- RBM19 | c.502G>T p.D168Y | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55694931; called by muse, mutect2, varscan2
- RECQL5 | c.1565T>A p.I522K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58643107; called by muse, mutect2, varscan2
- RFTN2 | c.1351C>A p.R451S | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV54390608; called by muse, mutect2, varscan2
- RGS7 | c.235C>A p.L79I | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as rs1464800121, COSV58542565, COSV58549685; called by muse, mutect2, varscan2
- RIMBP2 | c.2439G>C p.Q813H | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV55477986; called by muse, mutect2, varscan2
- RIMS1 | c.383G>A p.C128Y | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53467526; called by muse, mutect2, varscan2
- RNASE2 | c.131A>T p.N44I | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as COSV58941339; called by muse, mutect2, varscan2
- RNF144A | c.246G>T p.E82D | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.931); catalogued as COSV57983693; called by muse, mutect2, varscan2
- RP1L1 | c.3261G>T p.R1087S | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV66757423; called by muse, mutect2, varscan2
- RPS13 | c.295C>T p.R99* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | catalogued as COSV57180266, COSV99930524; called by muse, mutect2, varscan2
- RTCB | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 86/282 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53279540; called by muse, mutect2, varscan2
- RTL4 | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV61206723, COSV61207433; called by muse, mutect2
- RUNX1T1 | c.1279+2T>A p.X427_splice (on ENST00000265814 / NM_001198628.1; = p.X400_splice on NM_004349.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 8/240 reads (3%) | catalogued as COSV56154123; called by muse, mutect2
- RUNX1T1 | c.541G>T p.V181F (on ENST00000265814 / NM_001198628.1; = p.V154F on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56154151; called by muse, mutect2, varscan2
- SALL3 | c.2677A>T p.S893C | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV73306223; called by muse, mutect2, varscan2
- SASS6 | c.1576G>T p.G526W | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV54928935; called by muse, mutect2, varscan2
- SATL1 | c.890C>A p.P297Q (on ENST00000395409; = p.P484Q on NM_001012980.2) | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs146269642, COSV60577384; called by muse, mutect2, varscan2
- SCRN2 | c.968T>C p.M323T | Missense Mutation (SNP) | VAF 9/165 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV51636563; called by muse, mutect2
- SEC61A2 | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.742); catalogued as COSV53651095; called by muse, mutect2
- SECISBP2 | c.726G>T p.W242C | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV60529322; called by muse, mutect2, varscan2
- SEMA5A | c.2057G>T p.C686F | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66799135; called by muse, mutect2, varscan2
- SEPTIN4 | c.578T>C p.V193A | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.62); catalogued as rs112657072; called by muse, mutect2, varscan2
- SERPINA6 | c.260C>A p.A87D | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV58586160; called by muse, mutect2, varscan2
- SERPINB2 | c.246G>T p.M82I | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.067); catalogued as COSV55093461; called by muse, mutect2, varscan2
- SERPINB3 | c.286A>G p.T96A | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs1407061153, COSV52192714; called by muse, mutect2, varscan2
- SEZ6 | c.368C>T p.T123I | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV57982481; called by muse, mutect2, varscan2
- SHANK2 | c.5047G>T p.G1683C | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53607446, COSV53622383; called by muse, mutect2, varscan2
- SHANK2 | c.1928G>T p.G643V | Missense Mutation (SNP) | VAF 37/219 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53607470, COSV99574976; called by muse, mutect2, varscan2
- SI | c.4912C>A p.P1638T | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52288242; called by muse, mutect2, varscan2
- SI | c.315G>T p.W105C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs138564183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SIGLEC14 | c.940G>T p.G314* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | catalogued as COSV55781374; called by muse, mutect2, varscan2
- SIGLEC8 | c.719G>T p.R240L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs370112420, COSV58474653; called by muse, mutect2, varscan2
- SLC10A2 | c.1045T>G p.*349Eext*17 | Nonstop Mutation (SNP) | VAF 13/80 reads (16%) | catalogued as COSV55360401; called by muse, mutect2, varscan2
- SLC17A2 | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV55353344; called by muse, mutect2, varscan2
- SLC18A1 | c.1342G>T p.G448C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52349429; called by muse, mutect2, varscan2
- SLC1A3 | c.837G>T p.M279I | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54318215; called by muse, mutect2
- SLC25A12 | c.1664C>T p.T555M | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs765650566, COSV55534936; called by muse, mutect2, varscan2
- SLC26A3 | c.1506G>T p.R502S | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60641250; called by muse, mutect2, varscan2
- SLC26A7 | c.898C>G p.P300A | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1226502488, COSV52598132; called by muse, mutect2, varscan2
- SLC46A2 | c.1274T>C p.L425S | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV65289544; called by muse, mutect2, varscan2
- SLC6A19 | c.528G>A p.W176* | Nonsense Mutation (SNP) | VAF 20/121 reads (17%) | catalogued as rs765323895, COSV58672636; called by muse, mutect2, varscan2
- SLFN11 | c.1138C>A p.P380T | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.957); catalogued as COSV57697363, COSV57699593; called by muse, mutect2, varscan2
- SLITRK6 | c.1120A>T p.I374F | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.138); catalogued as COSV68390768; called by mutect2, varscan2
- SMARCAD1 | c.1716G>T p.K572N | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV62775231; called by muse, mutect2, varscan2
- SMCHD1 | c.551A>G p.D184G | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55262061; called by muse, mutect2
- SOST | c.522C>A p.H174Q | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as COSV100059638; called by muse, mutect2, varscan2
- SPAG1 | c.29G>T p.W10L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV52561135; called by muse, mutect2, varscan2
- SPDYE5 | c.813C>A p.H271Q | Missense Mutation (SNP) | VAF 66/274 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.232); catalogued as COSV71596386; called by muse, varscan2
- SPHKAP | c.4968T>A p.D1656E (on ENST00000392056 / NM_001142644.2; = p.D1627E on NM_030623.3) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.71); catalogued as COSV60885884; called by muse, mutect2, varscan2
- SPNS3 | c.404A>T p.Y135F | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV61070910; called by muse, mutect2, varscan2
- SPRR1B | c.47T>C p.L16P | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV61067820; called by muse, mutect2, varscan2
- SPRR2B | c.198G>T p.K66N | Missense Mutation (SNP) | VAF 79/294 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as COSV100482226; called by muse, mutect2, varscan2
- SPTA1 | c.4568C>T p.A1523V | Missense Mutation (SNP) | VAF 14/261 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63756367; called by muse, mutect2
- SPTA1 | c.3691del p.D1231Tfs*9 | Frame Shift Del (DEL) | VAF 33/144 reads (23%) | catalogued as COSV63751780; called by mutect2, pindel, varscan2
- SPTA1 | c.1919T>C p.I640T | Missense Mutation (SNP) | VAF 28/210 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs569603972, COSV63756373; called by muse, mutect2, varscan2
- SPZ1 | c.10T>A p.S4T | Missense Mutation (SNP) | VAF 109/341 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as COSV57063296; called by muse, mutect2, varscan2
- SSUH2 | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV58031581; called by muse, mutect2, varscan2
- STAC | c.293G>T p.R98M | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV56214197; called by muse, mutect2, varscan2
- STAT5A | c.834G>A p.W278* | Nonsense Mutation (SNP) | VAF 7/73 reads (10%) | catalogued as COSV61807579; called by muse, mutect2, varscan2
- STK11IP | c.2528G>T p.G843V | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV99822647; called by muse, mutect2, varscan2
- SYNE1 | c.21464G>T p.R7155L (on ENST00000367255 / NM_182961.4; = p.R7084L on NM_033071.3) | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54916739; called by muse, mutect2, varscan2
- SYNE1 | c.16361A>C p.N5454T (on ENST00000367255 / NM_182961.4; = p.N5383T on NM_033071.3) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as COSV55031977; called by muse, mutect2, varscan2
- TAF4B | c.410G>T p.R137I | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV52306748; called by muse, mutect2, varscan2
- TBX18 | c.1241C>A p.P414H | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV100858482; called by muse, mutect2, varscan2
- TBX18 | c.1240C>A p.P414T | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.864); catalogued as COSV100858483; called by muse, varscan2
- TBX4 | c.688T>G p.Y230D | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99540085; called by muse, mutect2, varscan2
- TCF25 | c.643A>T p.K215* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV54530337; called by muse, mutect2, varscan2
- TEX14 | c.2284G>C p.D762H (on ENST00000240361 / NM_001201457.2; = p.D756H on NM_031272.5) | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as rs1350984331, COSV53613459, COSV53618506; called by muse, mutect2, varscan2
- TG | c.1154A>T p.Q385L | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99600162; called by muse, mutect2
- TLK1 | c.20G>C p.S7T | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV62631328; called by muse, mutect2, varscan2
- TLL1 | c.807G>T p.Q269H | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.729); catalogued as COSV50303339; called by muse, mutect2, varscan2
- TLR4 | c.337C>A p.P113T (on ENST00000355622 / NM_138554.5; = p.P73T on NM_003266.4) | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62923039; called by muse, mutect2
- TMEM182 | c.437A>T p.Y146F | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV68425173; called by muse, mutect2, varscan2
- TNS1 | c.3022G>A p.E1008K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV50723456; called by muse, mutect2, varscan2
- TP53I11 | c.106G>T p.D36Y | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100370847, COSV57533586; called by muse, mutect2, varscan2
- TPH2 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as COSV104414879, COSV61592927; called by muse, mutect2, varscan2
- TRAPPC9 | c.2331G>T p.Q777H | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as COSV66904227; called by muse, mutect2, varscan2
- TRAV20 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs369305527; called by muse, mutect2, varscan2
- TRBV28 | c.80C>A p.S27* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as rs745393218; called by muse, mutect2, varscan2
- TRIM27 | c.1205C>G p.P402R | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65873752; called by muse, mutect2, varscan2
- TRIM40 | c.235T>A p.C79S | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV57157126; called by muse, mutect2, varscan2
- TRIM49 | c.41T>A p.I14N | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV61671300; called by mutect2, varscan2
- TRRAP | c.1847G>T p.R616L | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.393); catalogued as COSV62844129; called by muse, mutect2
- TSC2 | c.1062G>T p.Q354H | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54771153; called by muse, mutect2, varscan2
- TSGA10IP | c.1303C>G p.R435G | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV73245346; called by muse, mutect2, varscan2
- TTC21B | c.2422G>A p.A808T | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV54632491; called by muse, mutect2
- TTC7B | c.2026G>T p.A676S | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.138); catalogued as COSV60634624; called by muse, mutect2, varscan2
- TTLL7 | c.1471G>C p.E491Q | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.925); catalogued as COSV53085835; called by muse, mutect2, varscan2
- TTN | c.22490T>C p.L7497S (on ENST00000591111; = p.L6570S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/85 reads (5%) | PolyPhen probably damaging (0.909); catalogued as COSV60179850; called by muse, mutect2
- TTN | c.17403G>T p.R5801S (on ENST00000591111; = p.R4874S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | PolyPhen benign (0.344); catalogued as COSV60179861; called by muse, mutect2, varscan2
- TTN | c.15709C>A p.L5237M (on ENST00000591111; = p.L4310M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/190 reads (10%) | PolyPhen probably damaging (0.999); catalogued as COSV60179875; called by muse, mutect2, varscan2
- TUBA3D | c.226+1G>A p.X76_splice | Splice Site (SNP) | VAF 8/42 reads (19%) | catalogued as COSV58312486; called by muse, mutect2
- TUT7 | c.3316A>G p.I1106V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.859); catalogued as COSV52897031; called by muse, mutect2, varscan2
- UBR2 | c.2336A>G p.K779R | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV65751023; called by muse, mutect2, varscan2
- UBR2 | c.2875C>T p.P959S | Missense Mutation (SNP) | VAF 69/296 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as COSV65751036; called by muse, mutect2, varscan2
- UBR7 | c.822G>T p.K274N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV50150336; called by muse, mutect2, varscan2
- UGT1A1 | c.429C>A p.S143R | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV59392898; called by muse, mutect2
- UGT1A7 | c.659G>T p.C220F | Missense Mutation (SNP) | VAF 115/369 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as COSV60835453; called by muse, mutect2, varscan2
- UGT1A9 | c.653T>G p.L218* | Nonsense Mutation (SNP) | VAF 61/460 reads (13%) | catalogued as COSV60844241; called by muse, mutect2, varscan2
- UGT2B10 | c.1087G>T p.G363C | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs761612483, COSV55321795; called by muse, mutect2, varscan2
- ULK1 | c.1906A>G p.T636A | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV58858335; called by muse, varscan2
- ULK4 | c.899G>T p.R300I | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV57214503; called by muse, mutect2, varscan2
- UNC13C | c.5026C>A p.P1676T | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.073); catalogued as COSV52896320, COSV52928758; called by muse, mutect2
- UNC13C | c.5027C>A p.P1676H | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV52843474, COSV99514998; called by muse, mutect2
- UNC5C | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as COSV104437808, COSV71661077; called by muse, mutect2, varscan2
- UQCR11 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.259); catalogued as COSV73977267; called by muse, mutect2
- USH2A | c.12527C>A p.S4176Y | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV56397281; called by muse, mutect2, varscan2
- USH2A | c.10360G>T p.G3454W | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56397295; called by muse, mutect2, varscan2
- USH2A | c.5074G>C p.D1692H | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV56397328; called by muse, mutect2
- USH2A | c.3986T>A p.L1329* | Nonsense Mutation (SNP) | VAF 6/130 reads (5%) | catalogued as COSV56397347; called by muse, mutect2
- USP34 | c.8366A>T p.E2789V | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101276523, COSV68403414; called by muse, mutect2, varscan2
- USP6 | c.2488C>A p.L830I | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.021); catalogued as COSV51488310; called by muse, mutect2, varscan2
- USP8 | c.3275C>G p.S1092C | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV56162421, COSV56165934; called by muse, mutect2
- VN1R2 | c.1106G>T p.C369F | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.845); catalogued as COSV59037170; called by muse, mutect2, varscan2
- VPS16 | c.776G>A p.C259Y | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as COSV66796757; called by muse, mutect2, varscan2
- WDR53 | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.594); catalogued as COSV60284513; called by muse, mutect2, varscan2
- WDR62 | c.1012G>T p.G338W | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54337014; called by muse, mutect2
- WDR72 | c.2329A>G p.K777E | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.398); catalogued as COSV64750052; called by muse, mutect2, varscan2
- WNT10A | c.558G>T p.K186N | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.178); catalogued as COSV99297368; called by muse, mutect2, varscan2
- XIRP2 | c.1756G>A p.D586N (on ENST00000628543; = p.D761N on NM_152381.6) | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1275394926, COSV54714999; called by muse, mutect2, varscan2
- XRCC4 | c.867G>T p.Q289H | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.839); catalogued as COSV56538429; called by muse, mutect2, varscan2
- XYLT1 | c.1652G>T p.R551L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV54481925, COSV54489809; called by muse, mutect2, varscan2
- XYLT1 | c.1005C>A p.H335Q | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54489816; called by muse, mutect2, varscan2
- ZBED9 | c.3937G>C p.D1313H | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.993); catalogued as COSV71729586; called by muse, mutect2, varscan2
- ZBTB3 | c.1324A>G p.T442A | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.814); catalogued as COSV67361508; called by muse, mutect2, varscan2
- ZC3H15 | c.291T>G p.G97= | Splice Region (SNP) | VAF 22/77 reads (29%) | catalogued as COSV61922976; called by muse, mutect2, varscan2
- ZCCHC7 | c.260A>G p.D87G | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1216373344, COSV59719946, COSV59720285; called by muse, mutect2, varscan2
- ZCCHC9 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.705); catalogued as COSV99562628; called by muse, mutect2, varscan2
- ZEB1 | c.1170G>T p.M390I | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV58049023; called by muse, mutect2
- ZEB1 | c.2588C>G p.P863R | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.216); catalogued as rs202145455, COSV58049044; called by muse, mutect2, varscan2
- ZFHX4 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 6/45 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV51468785; called by muse, mutect2, varscan2
- ZFHX4 | c.5669C>A p.S1890Y | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as COSV51468908, COSV51480339, COSV99269107; called by muse, mutect2, varscan2
- ZFHX4 | c.9839G>T p.G3280V | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV50701146, COSV51468983; called by muse, mutect2, varscan2
- ZFPM2 | c.122C>A p.P41Q | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.276); catalogued as COSV68286841; called by muse, mutect2
- ZNF136 | c.1163G>T p.G388V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100677939; called by muse, mutect2, varscan2
- ZNF160 | c.1112G>T p.C371F | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62000223; called by muse, mutect2, varscan2
- ZNF235 | c.1898G>C p.G633A | Missense Mutation (SNP) | VAF 7/172 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV52157411; called by muse, mutect2
- ZNF239 | c.124A>G p.R42G | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100021755; called by muse, mutect2, varscan2
- ZNF260 | c.115A>T p.K39* | Nonsense Mutation (SNP) | VAF 14/139 reads (10%) | catalogued as COSV101591048; called by muse, mutect2, varscan2
- ZNF284 | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1366213816, COSV69691337; called by muse, mutect2, varscan2
- ZNF521 | c.1544G>T p.C515F | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64125042, COSV64129218; called by muse, mutect2, varscan2
- ZNF536 | c.1799C>A p.P600H | Missense Mutation (SNP) | VAF 68/168 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV62828297; called by muse, mutect2, varscan2
- ZNF536 | c.3751C>A p.P1251T | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); catalogued as COSV62828304; called by muse, mutect2, varscan2
- ZNF556 | c.118C>A p.L40M | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as COSV100298688, COSV56911310; called by muse, mutect2, varscan2
- ZNF571 | c.667T>C p.Y223H | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV100143682; called by muse, mutect2
- ZNF607 | c.916G>T p.E306* | Nonsense Mutation (SNP) | VAF 23/147 reads (16%) | catalogued as COSV62205729, COSV62205839; called by muse, mutect2, varscan2
- ZNF644 | c.1201A>T p.T401S | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.079); catalogued as CM146718, COSV61348825; called by muse, mutect2, varscan2
- ZNF665 | c.1334G>C p.G445A (on ENST00000600412; = p.G510A on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/211 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV67216256; called by muse, mutect2
- ZNF676 | c.413C>T p.T138I (on ENST00000650058; = p.T106I on NM_001001411.3) | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.934); catalogued as COSV68093856; called by muse, mutect2, varscan2
- ZNF71 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60148892; called by muse, mutect2, varscan2
- ZNF765 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV67182887; called by muse, mutect2, varscan2
- ZNF804A | c.1662G>T p.K554N | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV56458054; called by muse, mutect2
- ZNF827 | c.1237C>G p.R413G | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65229278; called by muse, mutect2, varscan2
- ZNF829 | c.161C>A p.A54D | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV66986659; called by muse, mutect2, varscan2
- ZNF831 | c.1849C>A p.Q617K | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV64042506; called by muse, mutect2, varscan2
- ZP4 | c.970G>C p.D324H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100850627, COSV63912641; called by muse, mutect2, varscan2
- ZRANB2 | c.757G>T p.G253W | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV54672883; called by muse, mutect2, varscan2
- ZRANB3 | c.2875G>C p.E959Q | Missense Mutation (SNP) | VAF 24/355 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.248); catalogued as COSV99923271; called by muse, mutect2
- ZSCAN2 | c.1796C>A p.S599Y | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV100306872; called by muse, mutect2, varscan2
- ZSCAN25 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV53553758; called by muse, mutect2
- ZSCAN4 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV59000679; called by muse, mutect2, varscan2
- ADGRD1 | c.323_331del p.S108_F110del | In Frame Del (DEL) | VAF 52/150 reads (35%) | called by mutect2, pindel, varscan2
- AKAP3 | c.508del p.S170Afs*5 | Frame Shift Del (DEL) | VAF 58/249 reads (23%) | called by mutect2, pindel, varscan2
- ARID1B | c.5838dup p.G1947Wfs*3 | Frame Shift Ins (INS) | VAF 26/202 reads (13%) | called by mutect2, pindel, varscan2
- ATOH1 | c.633del p.L211Ffs*92 | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | called by mutect2, varscan2
- BCL11B | c.1127C>T p.T376M (on ENST00000357195 / NM_001282237.2; = p.T305M on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- C16orf82 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- CPS1 | c.1095del p.M365Ifs*21 | Frame Shift Del (DEL) | VAF 23/142 reads (16%) | called by mutect2, pindel, varscan2
- CRYBG2 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- FLG | c.8938T>A p.S2980T | Missense Mutation (SNP) | VAF 40/636 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- GGNBP2 | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2
- KDR | c.3696del p.P1233Lfs*2 | Frame Shift Del (DEL) | VAF 14/104 reads (13%) | called by mutect2, pindel, varscan2
- KIAA1841 | c.653del p.C218Lfs*6 | Frame Shift Del (DEL) | VAF 25/129 reads (19%) | called by mutect2, pindel, varscan2
- KIDINS220 | c.1728del p.K576Nfs*2 | Frame Shift Del (DEL) | VAF 11/96 reads (11%) | called by mutect2, pindel, varscan2
- MROH1 | c.3446G>C p.W1149S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MUC16 | c.15857dup p.L5286Ffs*116 | Frame Shift Ins (INS) | VAF 19/96 reads (20%) | called by mutect2, pindel, varscan2
- RBP3 | c.2965C>A p.L989M | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- TOM1L1 | c.239_240del p.V80Afs*18 | Frame Shift Del (DEL) | VAF 13/84 reads (15%) | called by pindel, varscan2
- TRBV2 | c.107A>T p.Q36L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- TTN | c.40005A>T p.K13335N (on ENST00000591111; = p.K5911N on NM_003319.4) | Missense Mutation (SNP) | VAF 3/37 reads (8%) | PolyPhen benign (0.134); called by muse, mutect2
- UGGT1 | c.3716del p.X1239_splice | Splice Site (DEL) | VAF 16/134 reads (12%) | called by mutect2, pindel, varscan2
- XKR6 | c.1746del p.L584Sfs*19 | Frame Shift Del (DEL) | VAF 17/91 reads (19%) | called by mutect2, pindel, varscan2
- ZDHHC11 | c.1176_1177del p.L393Wfs*13 | Frame Shift Del (DEL) | VAF 24/92 reads (26%) | called by pindel, varscan2
- A1BG | c.306C>A p.T102= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as COSV54052088; called by muse, mutect2, varscan2
- AC092143.1 | c.1329G>C p.G443= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV59248256; called by muse, mutect2, varscan2
- ACAP3 | c.1689G>T p.V563= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100329738; called by muse, mutect2, varscan2
- ACKR1 | c.501G>T p.L167= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV63672090; called by muse, mutect2, varscan2
- ADGRE1 | c.1770C>T p.I590= | Silent (SNP) | VAF 7/97 reads (7%) | catalogued as COSV51677991, COSV51678122; called by muse, mutect2
- AFAP1L1 | c.1860G>T p.R620= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV57045295, COSV57046381; called by muse, mutect2, varscan2
- ASB9 | c.747C>T p.F249= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV66851990; called by muse, mutect2, varscan2
- BRINP3 | c.2217G>T p.V739= | Silent (SNP) | VAF 48/169 reads (28%) | catalogued as COSV66531088, COSV66535712; called by muse, mutect2, varscan2
- C2orf16 | c.5562C>G p.L1854= | Silent (SNP) | VAF 20/136 reads (15%) | catalogued as COSV62676858; called by muse, mutect2, varscan2
- C7orf33 | c.234G>T p.R78= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV61023475; called by muse, mutect2, varscan2
- CA6 | c.186C>A p.S62= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV101077472; called by muse, mutect2, varscan2
- CALCRL | c.732C>A p.A244= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV66475044, COSV66476024; called by muse, mutect2, varscan2
- CDCP2 | c.657C>A p.G219= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV61284674; called by muse, mutect2, varscan2
- CDH6 | c.1839G>T p.T613= | Silent (SNP) | VAF 23/119 reads (19%) | catalogued as COSV54073791, COSV54077831; called by muse, mutect2, varscan2
- CDH9 | c.1872C>A p.L624= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV50334733; called by muse, mutect2, varscan2
- CHRNB2 | c.768C>T p.F256= | Silent (SNP) | VAF 35/229 reads (15%) | catalogued as COSV63808873; called by muse, mutect2, varscan2
- CMBL | c.243G>A p.G81= | Silent (SNP) | VAF 32/94 reads (34%) | catalogued as rs776512208, COSV56984524; called by muse, mutect2, varscan2
- CNGB3 | c.1047T>C p.Y349= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV60693269; called by muse, mutect2, varscan2
- CXXC5 | c.189T>C p.G63= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100210659; called by mutect2, varscan2
- CYLD | c.1206C>G p.L402= | Silent (SNP) | VAF 22/262 reads (8%) | catalogued as COSV61095974; called by muse, mutect2
- DMBT1 | c.7131C>A p.V2377= (on ENST00000338354 / NM_001377530.1; = p.V1620= on NM_004406.3) | Silent (SNP) | VAF 36/170 reads (21%) | catalogued as COSV57551115, COSV57555576; called by muse, mutect2, varscan2
- DNAH5 | c.5442A>C p.T1814= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV54237872; called by muse, mutect2, varscan2
- DNAI4 | c.1569A>T p.I523= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as COSV64022600; called by muse, mutect2, varscan2
- DRD1 | c.24C>A p.A8= | Silent (SNP) | VAF 33/111 reads (30%) | catalogued as COSV101192426; called by muse, mutect2, varscan2
- DSCAM | c.1047C>A p.R349= | Silent (SNP) | VAF 61/175 reads (35%) | catalogued as COSV68030998; called by muse, mutect2, varscan2
- DST | c.16968G>A p.L5656= (on ENST00000361203 / NM_001374722.1; = p.L3353= on NM_015548.5) | Silent (SNP) | VAF 32/167 reads (19%) | catalogued as COSV55025589; called by muse, mutect2, varscan2
- DUSP21 | c.162C>A p.A54= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as COSV59134507; called by muse, mutect2, varscan2
- DYSF | c.3894C>T p.I1298= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV50470631; called by muse, mutect2, varscan2
- EDIL3 | c.486G>T p.L162= | Silent (SNP) | VAF 52/169 reads (31%) | catalogued as COSV56907819; called by muse, mutect2, varscan2
- ELFN2 | c.882G>T p.S294= | Silent (SNP) | VAF 46/152 reads (30%) | catalogued as COSV101297489, COSV68745306; called by muse, mutect2, varscan2
- EMC1 | c.156G>A p.K52= | Silent (SNP) | VAF 12/152 reads (8%) | catalogued as COSV61887029, COSV61887098; called by muse, mutect2
- EPHB2 | c.1071C>G p.V357= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as rs764855293, COSV65863967; called by muse, mutect2
- ERMARD | c.828A>G p.E276= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV64650866; called by muse, mutect2, varscan2
- EXPH5 | c.5347C>T p.L1783= | Silent (SNP) | VAF 8/178 reads (4%) | catalogued as COSV56204879; called by muse, mutect2
- FAM13C | c.1269G>T p.P423= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as rs772790700, COSV53248661, COSV53251952; called by muse, mutect2, varscan2
- FAM3B | c.450G>T p.L150= | Silent (SNP) | VAF 54/145 reads (37%) | catalogued as COSV100783725; called by muse, mutect2, varscan2
- FAM83D | c.993G>C p.R331= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as COSV54158132; called by muse, mutect2, varscan2
- FCN2 | c.42C>A p.T14= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV52477742; called by muse, mutect2, varscan2
- FN1 | c.2535T>C p.Y845= | Silent (SNP) | VAF 17/172 reads (10%) | catalogued as rs753408362, COSV60557739; called by muse, mutect2
- FREM1 | c.2289G>T p.G763= | Silent (SNP) | VAF 43/126 reads (34%) | catalogued as COSV66526419; called by muse, mutect2, varscan2
- FRMPD1 | c.4329A>C p.G1443= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV66701203; called by muse, mutect2, varscan2
- FUT11 | c.1260C>G p.A420= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV100226687; called by muse, mutect2, varscan2
- GABRG3 | c.1338G>T p.R446= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV61524137, COSV61535292; called by muse, mutect2, varscan2
- GCM1 | c.1062A>G p.P354= | Silent (SNP) | VAF 8/152 reads (5%) | catalogued as COSV52523052; called by muse, mutect2
- GGA3 | c.621G>A p.R207= (on ENST00000537686 / NM_138619.4; = p.R174= on NM_014001.5) | Silent (SNP) | VAF 19/224 reads (8%) | catalogued as rs1203134115, COSV55457612; called by muse, mutect2
- GMPS | c.561A>C p.A187= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV55810528; called by muse, mutect2, varscan2
- GNPAT | c.1455G>T p.L485= | Silent (SNP) | VAF 49/196 reads (25%) | catalogued as COSV64153801; called by muse, mutect2, varscan2
- GP2 | c.1167G>T p.G389= (on ENST00000381362 / NM_001007240.3; = p.G386= on NM_001502.4) | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV56895175; called by muse, mutect2
- GRIK5 | c.1908G>A p.T636= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs782719257, COSV53474656; called by muse, mutect2, varscan2
- HAO2 | c.174G>T p.V58= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV58040789; called by muse, mutect2, varscan2
- HENMT1 | c.933C>A p.V311= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV64230029, COSV64230419; called by muse, mutect2, varscan2
- HOXB9 | c.426G>T p.A142= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as rs773821975, COSV60817478; called by muse, mutect2, varscan2
- HOXD3 | c.618G>T p.L206= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV50882465; called by muse, mutect2, varscan2
- IFIT1B | c.1155C>A p.G385= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs1564804684, COSV65663583; called by muse, mutect2, varscan2
- IGKV1-16 | c.40C>T p.L14= | Silent (SNP) | VAF 18/177 reads (10%) | catalogued as rs1193856517; called by muse, varscan2
- IGKV1D-16 | c.282T>G p.T94= | Silent (SNP) | VAF 45/360 reads (13%) | called by muse, mutect2, varscan2
- IMPG2 | c.1104G>C p.L368= | Silent (SNP) | VAF 45/189 reads (24%) | catalogued as COSV51981712; called by muse, mutect2, varscan2
- JPH2 | c.1935G>C p.L645= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV65904501; called by muse, mutect2, varscan2
- KCNJ10 | c.1125C>A p.R375= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV63634271; called by muse, mutect2, varscan2
- KCNK13 | c.891G>C p.G297= | Silent (SNP) | VAF 9/130 reads (7%) | catalogued as COSV56414726; called by muse, mutect2
- KIF16B | c.3693G>A p.L1231= | Silent (SNP) | VAF 45/229 reads (20%) | catalogued as COSV61709389; called by muse, mutect2, varscan2
- KIF26B | c.2679G>A p.V893= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100832068; called by muse, mutect2, varscan2
- KIF2B | c.669C>G p.L223= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV52132836; called by muse, mutect2, varscan2
- KPRP | c.1662G>C p.R554= | Silent (SNP) | VAF 10/109 reads (9%) | catalogued as COSV64222220; called by muse, mutect2
- KRT33A | c.729G>T p.V243= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV99144835; called by muse, mutect2, varscan2
- KYNU | c.655C>T p.L219= | Silent (SNP) | VAF 8/124 reads (6%) | catalogued as rs1478527797, COSV99933050; called by muse, mutect2
- LILRA2 | c.1248G>T p.V416= | Silent (SNP) | VAF 15/132 reads (11%) | catalogued as COSV52193961; called by muse, mutect2, varscan2
- LONRF3 | c.1656T>C p.L552= (on ENST00000371628 / NM_001031855.3; = p.L511= on NM_024778.5) | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV59154492; called by muse, mutect2, varscan2
- LPIN2 | c.2217C>A p.G739= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV55241560; called by muse, mutect2, varscan2
- LRRC66 | c.1212G>C p.L404= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV58635114; called by muse, mutect2, varscan2
- MANBA | c.2256T>C p.G752= (on ENST00000642252; = p.G706= on NM_005908.4) | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV56967760; called by muse, mutect2, varscan2
- MED12L | c.5190G>T p.L1730= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs1446727225, COSV56386412; called by muse, mutect2, varscan2
- MFSD13A | c.999G>T p.A333= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV53268169; called by muse, mutect2, varscan2
- MUC16 | c.31767T>C p.S10589= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV67478330; called by muse, mutect2, varscan2
- MUC16 | c.28179A>T p.P9393= | Silent (SNP) | VAF 30/143 reads (21%) | catalogued as COSV67478334; called by muse, mutect2, varscan2
- MYH7 | c.48G>T p.L16= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV62521218; called by muse, mutect2, varscan2
- MYT1L | c.1179G>A p.S393= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs368168562; called by muse, mutect2, varscan2
- NALCN | c.303C>A p.S101= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as COSV51948570; called by muse, mutect2, varscan2
- NAV3 | c.3159C>T p.P1053= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as COSV57094649, COSV99886246; called by muse, mutect2, varscan2
- NDUFA8 | c.222A>C p.I74= | Silent (SNP) | VAF 9/104 reads (9%) | catalogued as COSV101056789; called by muse, mutect2
- NLRP11 | c.1578G>A p.V526= | Silent (SNP) | VAF 42/238 reads (18%) | catalogued as rs753550480, COSV64088171; called by muse, mutect2, varscan2
- NTRK1 | c.1671C>T p.F557= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100693303; called by muse, mutect2, varscan2
- OR10A2 | c.144C>T p.F48= | Silent (SNP) | VAF 17/260 reads (7%) | catalogued as COSV100225006; called by muse, mutect2
- OR13D1 | c.435C>A p.V145= | Silent (SNP) | VAF 12/162 reads (7%) | catalogued as COSV59514305; called by muse, mutect2
- OR2D2 | c.213C>T p.L71= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV55057618; called by muse, mutect2, varscan2
- OR52A5 | c.628C>T p.L210= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as COSV100263378; called by muse, mutect2, varscan2
- OR52A5 | c.627C>A p.I209= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV100263382; called by muse, mutect2, varscan2
- OR52E4 | c.46C>T p.L16= | Silent (SNP) | VAF 52/252 reads (21%) | catalogued as COSV57625431; called by muse, mutect2, varscan2
- OR52E6 | c.660C>A p.I220= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as COSV100259262, COSV100259488; called by muse, mutect2
- OR52N4 | c.456G>C p.L152= | Silent (SNP) | VAF 33/151 reads (22%) | catalogued as COSV57891766; called by muse, mutect2, varscan2
- OR52R1 | c.558T>A p.A186= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV61888866; called by muse, mutect2
- OR56A4 | c.45C>T p.G15= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV100417734, COSV58111062; called by muse, mutect2, varscan2
- OR5H15 | c.207G>A p.V69= | Silent (SNP) | VAF 58/356 reads (16%) | catalogued as rs779237005, COSV62948541; called by muse, varscan2
- OR6B2 | c.321G>C p.L107= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV53155388; called by mutect2, varscan2
- P2RX2 | c.609C>A p.I203= (on ENST00000343948 / NM_170683.4; = p.I131= on NM_012226.5) | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV57684768; called by muse, mutect2, varscan2
- PAMR1 | c.1962C>A p.P654= (on ENST00000619888 / NM_001001991.3; = p.P671= on NM_015430.4) | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs747015590, COSV53514164, COSV53515930; called by muse, mutect2, varscan2
- PARN | c.1677A>T p.T559= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV58368091; called by muse, mutect2, varscan2
- PCDHGB3 | c.237C>A p.P79= | Silent (SNP) | VAF 89/295 reads (30%) | catalogued as rs1192871928, COSV53983575; called by muse, mutect2, varscan2
- PCLO | c.3873A>T p.P1291= | Silent (SNP) | VAF 42/195 reads (22%) | catalogued as COSV61648335; called by muse, mutect2, varscan2
- PEG3 | c.1863T>C p.Y621= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV55639388; called by muse, mutect2, varscan2
- PEX5 | c.1557C>T p.P519= (on ENST00000420616; = p.P511= on NM_000319.5) | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV56956454; called by muse, mutect2, varscan2
- PIEZO2 | c.8103T>C p.L2701= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV53291608; called by muse, mutect2, varscan2
- PIKFYVE | c.2265A>T p.T755= | Silent (SNP) | VAF 7/169 reads (4%) | catalogued as COSV52244703; called by muse, mutect2
- PPP1R15A | c.1593G>T p.L531= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV52339580; called by muse, mutect2, varscan2
- PRKN | c.571C>A p.R191= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV58216273, COSV58263244; called by muse, mutect2, varscan2
- PRSS27 | c.54G>A p.Q18= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100234512; called by muse, mutect2
- RAB15 | c.165C>T p.I55= | Silent (SNP) | VAF 21/154 reads (14%) | catalogued as COSV50824393, COSV50824975; called by muse, mutect2, varscan2
- RNPS1 | c.504C>T p.L168= | Silent (SNP) | VAF 8/109 reads (7%) | catalogued as rs926305907, COSV57047178; called by muse, mutect2
- RORB | c.723C>T p.T241= (on ENST00000396204 / NM_001365023.1; = p.T230= on NM_006914.4) | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as COSV65337816; called by muse, mutect2
- RP1 | c.5070A>T p.S1690= | Silent (SNP) | VAF 83/182 reads (46%) | catalogued as COSV55121052; called by muse, mutect2, varscan2
- RTL9 | c.369T>A p.S123= | Silent (SNP) | VAF 46/108 reads (43%) | catalogued as COSV101511660; called by muse, mutect2, varscan2
- RYR3 | c.13866C>A p.L4622= (on ENST00000389232; = p.L4623= on NM_001036.6) | Silent (SNP) | VAF 37/258 reads (14%) | catalogued as COSV66799545; called by muse, mutect2, varscan2
- SEC31A | c.513C>A p.I171= | Silent (SNP) | VAF 9/133 reads (7%) | catalogued as COSV52347902; called by muse, mutect2
- SFMBT2 | c.1173G>T p.A391= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV62812649; called by muse, mutect2, varscan2
- SIPA1L1 | c.4221G>T p.L1407= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV62171672; called by muse, mutect2, varscan2
- SLC32A1 | c.1362G>T p.A454= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV54147461; called by muse, mutect2, varscan2
- SLC39A12 | c.1911T>A p.T637= (on ENST00000377369 / NM_001145195.2; = p.T600= on NM_152725.3) | Silent (SNP) | VAF 25/167 reads (15%) | catalogued as COSV66200409; called by muse, mutect2, varscan2
- SLC45A2 | c.1353C>T p.R451= | Silent (SNP) | VAF 97/376 reads (26%) | catalogued as rs750872312, COSV56873364; called by muse, mutect2, varscan2
- SOBP | c.2526G>C p.P842= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as COSV58000291; called by muse, mutect2, varscan2
- SPTA1 | c.4683G>T p.L1561= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as COSV63756365; called by muse, mutect2
- ST3GAL1 | c.1005G>T p.R335= | Silent (SNP) | VAF 9/143 reads (6%) | catalogued as COSV60614595; called by muse, mutect2
- STK10 | c.2124G>C p.L708= | Silent (SNP) | VAF 47/159 reads (30%) | catalogued as COSV51576296; called by muse, mutect2, varscan2
- SYDE2 | c.598C>T p.L200= | Silent (SNP) | VAF 16/218 reads (7%) | catalogued as COSV52316548; called by muse, mutect2
- TFAP4 | c.750C>T p.V250= | Silent (SNP) | VAF 16/147 reads (11%) | catalogued as rs576796776, COSV52598330; called by muse, mutect2, varscan2
- TMEM169 | c.85C>T p.L29= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as rs769016269, COSV99824458; called by muse, mutect2, varscan2
- TMEM38A | c.828G>A p.S276= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as rs142098397; called by muse, mutect2, varscan2
- TNFRSF13B | c.141C>T p.C47= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs1002042381, COSV55428828; called by muse, mutect2, varscan2
- TOMM40L | c.576G>T p.G192= | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as COSV100915610; called by muse, mutect2, varscan2
- TRIM60 | c.243C>A p.L81= | Silent (SNP) | VAF 5/98 reads (5%) | catalogued as COSV61971002; called by muse, mutect2
- TSEN2 | c.1065G>T p.V355= | Silent (SNP) | VAF 36/160 reads (23%) | catalogued as COSV53189744; called by muse, mutect2, varscan2
- TSHR | c.1425C>A p.L475= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as rs1380568665, COSV53325452; called by muse, mutect2, varscan2
- TTN | c.89403C>A p.G29801= (on ENST00000591111; = p.G22377= on NM_003319.4) | Silent (SNP) | VAF 50/385 reads (13%) | catalogued as COSV60179820; called by muse, mutect2, varscan2
- TUT1 | c.1044C>T p.L348= | Silent (SNP) | VAF 9/122 reads (7%) | catalogued as COSV53470894; called by muse, mutect2
- TYRO3 | c.2430T>C p.A810= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV55484786; called by mutect2, varscan2
- USPL1 | c.2847C>T p.A949= | Silent (SNP) | VAF 29/161 reads (18%) | catalogued as COSV55000809; called by muse, mutect2, varscan2
- VAC14 | c.1233G>T p.T411= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV55751310; called by muse, mutect2, varscan2
- WBP2 | c.24G>A p.S8= | Silent (SNP) | VAF 28/302 reads (9%) | catalogued as COSV54663814, COSV54664270; called by muse, mutect2
- WDFY3 | c.240C>T p.F80= | Silent (SNP) | VAF 12/145 reads (8%) | catalogued as COSV55706943; called by muse, mutect2
- WDR17 | c.1362G>T p.G454= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV54578098; called by muse, mutect2, varscan2
- WDR6 | c.1002A>C p.G334= | Silent (SNP) | VAF 5/92 reads (5%) | catalogued as COSV58245850; called by muse, mutect2
- XPR1 | c.1539G>T p.L513= | Silent (SNP) | VAF 61/229 reads (27%) | catalogued as COSV62558470; called by muse, mutect2, varscan2
- YARS1 | c.483G>A p.L161= | Silent (SNP) | VAF 16/202 reads (8%) | catalogued as COSV65114518; called by muse, mutect2
- ZNF217 | c.1917C>G p.L639= | Silent (SNP) | VAF 14/330 reads (4%) | catalogued as COSV56596662, COSV56601550; called by muse, mutect2
- ZNF284 | c.1173G>T p.R391= | Silent (SNP) | VAF 43/174 reads (25%) | catalogued as COSV69691341; called by muse, mutect2, varscan2
- ZNF354B | c.180A>T p.P60= | Silent (SNP) | VAF 9/123 reads (7%) | catalogued as COSV100482957; called by muse, mutect2
- ZNF536 | c.159G>T p.R53= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV62828288; called by muse, mutect2, varscan2
- ZNF746 | c.768C>T p.L256= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV61408153; called by muse, mutect2
- ZNFX1 | c.312G>A p.R104= | Silent (SNP) | VAF 55/370 reads (15%) | catalogued as rs770977004, COSV65576724; called by muse, mutect2, varscan2
- ZSCAN5B | c.1077G>T p.V359= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as COSV62000592; called by muse, mutect2, varscan2
- CCNQP1 | n.495C>A | RNA (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- CR1 | c.487+12103T>A | Intron (SNP) | VAF 58/209 reads (28%) | catalogued as COSV100887521; called by muse, mutect2, varscan2
- DST | c.4297-1920G>T | Intron (SNP) | VAF 16/90 reads (18%) | catalogued as COSV99754094; called by muse, mutect2, varscan2
- ERCC6 | c.1397+7270G>A | Intron (SNP) | VAF 9/79 reads (11%) | catalogued as rs760332508, COSV63389546; called by muse, mutect2, varscan2
- FRMPD2B | n.1027G>T | RNA (SNP) | VAF 19/94 reads (20%) | called by mutect2, varscan2
- MASP1 | c.1303+5465T>C | Intron (SNP) | VAF 12/103 reads (12%) | catalogued as COSV99962114; called by muse, mutect2, varscan2
- MIR1283-1 | n.3C>G | RNA (SNP) | VAF 9/163 reads (6%) | called by muse, mutect2
- MIR498 | n.96C>A | RNA (SNP) | VAF 17/114 reads (15%) | called by muse, mutect2, varscan2
- MORF4 | n.852G>A | RNA (SNP) | VAF 9/132 reads (7%) | called by muse, mutect2
- NCAM1 | c.2131+2549T>A | Intron (SNP) | VAF 16/64 reads (25%) | catalogued as COSV100377424; called by muse, mutect2
- NCAM1 | c.2131+2551C>A | Intron (SNP) | VAF 17/64 reads (27%) | catalogued as COSV100377426; called by muse, mutect2
- PDE4B | c.281+74111G>A | Intron (SNP) | VAF 5/79 reads (6%) | catalogued as COSV100303081; called by muse, mutect2
- PTPA | chr9:129111019 C>T | 5'Flank (SNP) | VAF 9/66 reads (14%) | catalogued as COSV100533996; called by muse, mutect2, varscan2
- RBFOX1 | c.28-185129G>C | Intron (SNP) | VAF 21/205 reads (10%) | catalogued as rs200160011, COSV100300696; called by muse, mutect2, varscan2
- RBFOX1 | c.931-5207C>A | Intron (SNP) | VAF 21/99 reads (21%) | catalogued as rs1028513925, COSV100300699; called by muse, mutect2, varscan2
- RBM44 | c.-98-2698G>T | Intron (SNP) | VAF 8/22 reads (36%) | catalogued as COSV57631412; called by muse, mutect2, varscan2
- SNORD116-6 | n.83C>A | RNA (SNP) | VAF 20/131 reads (15%) | called by muse, mutect2, varscan2
- ST8SIA2 | chr15:92473050 C>T | 3'Flank (SNP) | VAF 10/94 reads (11%) | catalogued as rs1442675391; called by muse, mutect2, varscan2
- SV2C | c.581-20867A>T | Intron (SNP) | VAF 37/142 reads (26%) | called by muse, mutect2, varscan2
- TTN | c.10361-5246G>C | Intron (SNP) | VAF 37/128 reads (29%) | catalogued as COSV60179889; called by muse, mutect2, varscan2
- TTN | c.10360+2038A>T | Intron (SNP) | VAF 31/175 reads (18%) | catalogued as COSV60179896; called by muse, mutect2, varscan2
- TUBB7P | n.184C>A | RNA (SNP) | VAF 21/71 reads (30%) | catalogued as rs782177608; called by muse, mutect2, varscan2
- XIST | n.8400G>T | RNA (SNP) | VAF 17/94 reads (18%) | called by muse, mutect2, varscan2
